Somatic mutation profile of tumor specimen HCM-BROD-0694-C43-06A (aliquot HCM-BROD-0694-C43-06A-01D-A83U-36) from HCMI case HCM-BROD-0694-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 45.9 years (16,765 days).
Specimen HCM-BROD-0694-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a325edd8-3206-441a-a06e-f9bce0b56308.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0694-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0694-C43-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a195202-fdb0-42ed-b89e-a1ee7ab39c82

The open-access MAF lists 756 somatic variants for this specimen: 474 protein-altering or splice-affecting, 252 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 436, Silent 252, Nonsense Mutation 21, Intron 14, Splice Region 9, Frame Shift Del 6, 5'Flank 5, 5'UTR 4, 3'Flank 3, RNA 2, 3'UTR 2, Translation Start Site 1.

Variants (750 of 756; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 153/433 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57595738; called by muse, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 176/456 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- SYNJ1 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 121/261 reads (46%) | catalogued as rs1569075471, COSV59145375; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 108/462 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746782619; called by muse, mutect2, varscan2
- ABI3 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 314/880 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139297199; called by muse, mutect2, varscan2
- ACRBP | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 196/596 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV57524667; called by muse, mutect2, varscan2
- ACSM4 | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 89/282 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV101257124; called by muse, mutect2, varscan2
- ACTRT1 | c.344C>A p.P115H | Missense Mutation (SNP) | VAF 228/700 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64419229, COSV64419284; called by muse, mutect2, varscan2
- ADAMTS2 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 194/429 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.254); catalogued as rs763890617, COSV99200985; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.9770C>T p.S3257F | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV67994124; called by muse, mutect2, varscan2
- ADH6 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 104/429 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs528740741; called by muse, mutect2, varscan2
- ADRA1A | c.1363C>T p.H455Y | Missense Mutation (SNP) | VAF 133/451 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); catalogued as rs866461368; called by muse, mutect2, varscan2
- AKR1D1 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 136/453 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867274244, COSV54338660; called by muse, mutect2, varscan2
- ANAPC5 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 87/312 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV55845526; called by muse, mutect2, varscan2
- ANTXR2 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1397015975; called by muse, mutect2
- AQP11 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 263/814 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV57992432; called by muse, mutect2, varscan2
- ARF1 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 158/538 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.125); catalogued as rs776377227; called by muse, mutect2, varscan2
- ARHGAP17 | c.2264C>T p.P755L (on ENST00000289968 / NM_001006634.3; = p.P677L on NM_018054.6) | Missense Mutation (SNP) | VAF 301/855 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1477824638; called by muse, mutect2, varscan2
- ARHGEF15 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 314/890 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200249246, COSV62724288; ClinVar: uncertain significance; called by muse, varscan2
- ARHGEF15 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 340/919 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs769948298; called by muse, varscan2
- ASB17 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV52409524; called by muse, mutect2, varscan2
- ATG9B | c.752G>A p.R251K | Missense Mutation (SNP) | VAF 165/560 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs768574601, COSV65058269; called by muse, mutect2, varscan2
- ATP12A | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 116/352 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54520735; called by muse, mutect2, varscan2
- BBX | c.1258A>G p.S420G | Missense Mutation (SNP) | VAF 118/358 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.114); catalogued as rs1560133621; called by muse, mutect2, varscan2
- BCLAF1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 79/506 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as COSV62140394; called by muse, mutect2, varscan2
- BRDT | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV62864459; called by muse, mutect2, varscan2
- BRS3 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 104/357 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65710939; called by muse, mutect2, varscan2
- C12orf50 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 59/229 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs1436631609; called by muse, mutect2, varscan2
- C16orf96 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 135/490 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as rs1180533213; called by muse, mutect2, varscan2
- C8orf89 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 84/300 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1428373209; called by muse, mutect2, varscan2
- CACNA1C | c.4564C>T p.R1522W | Missense Mutation (SNP) | VAF 182/515 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1189801745; called by muse, mutect2, varscan2
- CACNG5 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 183/565 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as rs868347222; called by muse, mutect2, varscan2
- CAMK4 | c.1358G>A p.G453E | Missense Mutation (SNP) | VAF 154/295 reads (52%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV56661567; called by muse, mutect2, varscan2
- CATSPERB | c.1081C>T p.L361F | Missense Mutation (SNP) | VAF 95/365 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs545114453, COSV56424106, COSV56432713; called by muse, mutect2, varscan2
- CD2AP | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 96/316 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs756790635, COSV100830695; called by muse, mutect2, varscan2
- CFH | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 127/449 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs746222626, CM1512032, COSV62778762; called by muse, mutect2, varscan2
- CGNL1 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 130/349 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs376234948; called by muse, mutect2, varscan2
- CHD5 | c.1571C>T p.S524F | Missense Mutation (SNP) | VAF 155/479 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV99315508; called by muse, mutect2, varscan2
- CHIT1 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 114/381 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs747602221; called by muse, mutect2, varscan2
- COL5A3 | c.5101G>A p.G1701R | Missense Mutation (SNP) | VAF 132/386 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs531037970; called by muse, mutect2, varscan2
- COL6A6 | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 127/406 reads (31%) | catalogued as COSV62031799; called by muse, mutect2, varscan2
- COMMD10 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1314043352; called by muse, mutect2, varscan2
- COQ8B | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 145/559 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54687970; called by muse, mutect2, varscan2
- COQ8B | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 145/563 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754265164; called by muse, mutect2, varscan2
- CRP | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 154/495 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1443763167; called by muse, mutect2, varscan2
- CRYBG1 | c.4574T>C p.V1525A | Missense Mutation (SNP) | VAF 90/266 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs758680944; called by muse, mutect2, varscan2
- CSMD1 | c.6224G>A p.G2075E (on ENST00000520002; = p.G2074E on NM_033225.6) | Missense Mutation (SNP) | VAF 113/347 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601893; called by muse, mutect2, varscan2
- CSMD2 | c.9627G>A p.M3209I | Missense Mutation (SNP) | VAF 242/756 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV99587252; called by muse, mutect2, varscan2
- CSTF1 | c.1283C>T p.S428L | Missense Mutation (SNP) | VAF 126/385 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs865777609, COSV99410225; called by muse, mutect2, varscan2
- CYP2D7 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 215/621 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1283269919; called by muse, mutect2, varscan2
- DENND11 | c.366C>T p.F122= | Splice Region (SNP) | VAF 197/412 reads (48%) | catalogued as rs267601318; called by muse, mutect2, varscan2
- DEPDC5 | c.2018C>T p.A673V (on ENST00000400246; = p.A742V on NM_014662.5) | Missense Mutation (SNP) | VAF 188/648 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56712245; called by muse, mutect2, varscan2
- DEUP1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 78/325 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs780964725, COSV53215778; called by muse, mutect2, varscan2
- DGKB | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs377479103; called by muse, mutect2, varscan2
- DHX38 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 114/400 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV51701326; called by muse, mutect2, varscan2
- DNAH5 | c.13853C>T p.A4618V | Missense Mutation (SNP) | VAF 129/405 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1018054486; called by muse, mutect2, varscan2
- DNAH5 | c.9130G>A p.E3044K | Missense Mutation (SNP) | VAF 87/326 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54236590; called by muse, mutect2, varscan2
- DNAH9 | c.2861C>G p.T954S | Missense Mutation (SNP) | VAF 182/574 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs779497370; called by muse, mutect2, varscan2
- DNAI3 | c.2585A>G p.Y862C | Missense Mutation (SNP) | VAF 114/285 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs755694782; called by muse, mutect2, varscan2
- DOCK7 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 112/364 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV52001441; called by muse, mutect2, varscan2
- DOK2 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 264/833 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs751346454, COSV52388940; called by muse, mutect2, varscan2
- DPEP2 | c.1417C>T p.L473F | Missense Mutation (SNP) | VAF 112/436 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.028); catalogued as COSV99263105; called by muse, mutect2, varscan2
- DPP9 | c.910C>T p.R304W (on ENST00000598800; = p.R333W on NM_139159.5) | Missense Mutation (SNP) | VAF 125/366 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756602514, COSV53591178; called by muse, mutect2, varscan2
- DYSF | c.3196G>A p.G1066S | Missense Mutation (SNP) | VAF 209/675 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.127); catalogued as COSV50338230; called by muse, mutect2, varscan2
- EBF3 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 256/496 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV62471285; called by muse, mutect2, varscan2
- EIF2A | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 102/392 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs746915859, COSV56406061; called by muse, mutect2, varscan2
- EIF4G2 | c.1043G>A p.S348N | Missense Mutation (SNP) | VAF 109/435 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1347062058; called by muse, mutect2, varscan2
- EMC7 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 238/782 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV56626427; called by muse, varscan2
- EVC2 | c.3505C>T p.H1169Y | Missense Mutation (SNP) | VAF 183/744 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.25); catalogued as rs747562782; ClinVar: uncertain significance; called by muse, mutect2
- F8 | c.4388C>T p.S1463F | Missense Mutation (SNP) | VAF 150/426 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV64272666, COSV64275078, COSV64276696; called by muse, mutect2, varscan2
- FAAH | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 139/409 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs1353971045, COSV54545452; called by muse, mutect2, varscan2
- FAM135B | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 106/319 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV52725538, COSV52758416; called by muse, mutect2, varscan2
- FAM216B | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 91/326 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as rs1203119314; called by muse, mutect2, varscan2
- FASLG | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 128/407 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60679817; called by muse, mutect2, varscan2
- FCAMR | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 148/468 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as COSV61367167; called by muse, mutect2, varscan2
- FHOD3 | c.2558C>T p.P853L (on ENST00000359247 / NM_001281739.3; = p.P870L on NM_025135.5) | Missense Mutation (SNP) | VAF 68/250 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.466); catalogued as rs982347747, COSV57174237, COSV57188730, COSV99068630; called by mutect2, varscan2
- GANAB | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 128/441 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV60463202; called by muse, mutect2, varscan2
- GCNA | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 139/448 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV101032670; called by muse, mutect2, varscan2
- GLP2R | c.619C>T p.H207Y | Missense Mutation (SNP) | VAF 123/331 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1222025433; called by muse, mutect2, varscan2
- GON4L | c.3916C>T p.P1306S | Missense Mutation (SNP) | VAF 120/407 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.343); catalogued as rs775318160, COSV55193989; called by muse, mutect2, varscan2
- GRXCR1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 197/593 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV67674780; called by muse, mutect2, varscan2
- HEATR5A | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 136/462 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as COSV66344653; called by muse, mutect2, varscan2
- HHIP | c.818A>C p.Q273P | Missense Mutation (SNP) | VAF 99/300 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs771500415; called by muse, mutect2, varscan2
- HS6ST3 | c.1373G>A p.G458E | Missense Mutation (SNP) | VAF 142/510 reads (28%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.084); catalogued as rs1331474154, COSV65014061; called by muse, mutect2, varscan2
- HUWE1 | c.11789C>T p.S3930F | Missense Mutation (SNP) | VAF 153/296 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV99474642; called by muse, mutect2, varscan2
- IAPP | c.80G>A p.S27N | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs1286099292, COSV53714316; called by muse, mutect2, varscan2
- ICE1 | c.3932C>T p.S1311F | Missense Mutation (SNP) | VAF 101/280 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as rs762287463; called by muse, mutect2, varscan2
- IL1RL2 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as rs267598803, COSV99960396; called by muse, mutect2, varscan2
- IL21R | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 238/750 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as rs1294802701; called by muse, varscan2
- INSM2 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 331/965 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as rs1355308438; called by muse, mutect2, varscan2
- IRAK4 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV71211045; called by muse, mutect2, varscan2
- ITCH | c.1915C>T p.R639C (on ENST00000262650 / NM_001257137.3; = p.R598C on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 225/304 reads (74%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.953); catalogued as rs757758667, COSV99391853; called by muse, mutect2, varscan2
- ITGA2B | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 219/648 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1248600377; called by muse, mutect2, varscan2
- ITGB4 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 112/361 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs886053409, COSV52322502, COSV52324788, COSV52332573; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNA6 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 181/506 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV99768883; called by muse, mutect2, varscan2
- KCNJ1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 133/451 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV60661536; called by muse, mutect2, varscan2
- KCNJ16 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 186/584 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52255799; called by muse, mutect2, varscan2
- KCNK13 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 167/498 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56410433; called by muse, mutect2, varscan2
- KCNQ3 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 165/551 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867625794, COSV66476278; called by muse, mutect2, varscan2
- LANCL1 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 131/313 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs562369667; called by muse, mutect2, varscan2
- LGALS4 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 148/437 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.786); catalogued as rs760235320; called by muse, mutect2, varscan2
- LMLN | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1560139884; called by muse, mutect2, varscan2
- LRP1B | c.13018G>A p.D4340N | Missense Mutation (SNP) | VAF 105/347 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV101251919; called by muse, mutect2, varscan2
- MAGEA6 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 97/443 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as rs782585304; called by muse, mutect2, varscan2
- MAGEB3 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 212/428 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs868499328, COSV64396698, COSV64397767; called by muse, mutect2, varscan2
- MAGEC1 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 138/439 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.058); catalogued as COSV99594673; called by muse, mutect2, varscan2
- MAGEC3 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 135/460 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV53580592; called by muse, mutect2, varscan2
- MALRD1 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV71054833; called by muse, mutect2, varscan2
- MALRD1 | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 80/185 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV71054835; called by muse, mutect2, varscan2
- MAP7 | c.1838C>T p.T613I | Missense Mutation (SNP) | VAF 88/336 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as rs755562038; called by muse, mutect2, varscan2
- MARK1 | c.1559G>A p.G520E | Missense Mutation (SNP) | VAF 98/318 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV65066056; called by muse, mutect2, varscan2
- MCTP2 | c.1853G>A p.G618E | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780515255, COSV59144360; called by muse, mutect2, varscan2
- MEP1B | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 93/382 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.052); catalogued as COSV52496942; called by muse, mutect2, varscan2
- MFHAS1 | c.3017C>T p.P1006L | Missense Mutation (SNP) | VAF 60/307 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV52287684; called by muse, mutect2
- MGAM | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 117/577 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs373200528; called by muse, mutect2, varscan2
- MRGPRX1 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 128/399 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.381); catalogued as rs768526268; called by muse, mutect2, varscan2
- MSR1 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 137/357 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.656); catalogued as COSV50506846; called by muse, mutect2, varscan2
- MTMR11 | c.289G>A p.D97N (on ENST00000439741 / NM_001145862.2; = p.D25N on NM_181873.3) | Missense Mutation (SNP) | VAF 134/530 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1314893872; called by muse, varscan2
- MUC20 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 255/517 reads (49%) | SIFT deleterious, low confidence (0); catalogued as rs768011902; called by muse, mutect2, varscan2
- MUC4 | c.5741C>T p.S1914F | Missense Mutation (SNP) | VAF 121/905 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as COSV62143904; called by muse, mutect2, varscan2
- MYEF2 | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 93/265 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV51046244, COSV51048439; called by muse, mutect2, varscan2
- MYH1 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 174/522 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs200860839; called by muse, mutect2, varscan2
- MYH15 | c.3808G>A p.E1270K | Missense Mutation (SNP) | VAF 81/316 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56306777; called by muse, mutect2, varscan2
- MYH2 | c.5364G>A p.M1788I | Missense Mutation (SNP) | VAF 123/423 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as rs775090913; called by muse, mutect2, varscan2
- MYH8 | c.3688G>A p.E1230K | Missense Mutation (SNP) | VAF 150/384 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs1283060152, COSV67962722; called by muse, mutect2, varscan2
- MYL7 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 152/525 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1215355446, COSV56268746; called by muse, mutect2, varscan2
- NBN | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs730881856, COSV55376044; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- NCF2 | c.411G>A p.W137* | Nonsense Mutation (SNP) | VAF 138/438 reads (32%) | catalogued as COSV62315083; called by muse, mutect2, varscan2
- NCKAP1L | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 66/227 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as COSV99515416; called by muse, mutect2, varscan2
- NDUFS8 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 330/934 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs780737143; called by muse, mutect2, varscan2
- NEK5 | c.216G>A p.E72= | Splice Region (SNP) | VAF 95/283 reads (34%) | catalogued as COSV62879839; called by muse, mutect2, varscan2
- NEU1 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 222/777 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99998598; called by muse, mutect2, varscan2
- NFE2L3 | c.927A>G p.I309M | Missense Mutation (SNP) | VAF 136/391 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as rs1397632432; called by muse, mutect2, varscan2
- NGF | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 162/310 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772557857, COSV101049373, COSV65686846; called by muse, mutect2, varscan2
- NLRP12 | c.2507G>A p.G836E | Missense Mutation (SNP) | VAF 157/516 reads (30%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.995); catalogued as COSV100144968, COSV60743784; called by muse, mutect2, varscan2
- NLRP12 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 148/469 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.207); catalogued as COSV60746803; called by muse, mutect2, varscan2
- NPAS1 | c.525G>A p.V175= | Splice Region (SNP) | VAF 162/459 reads (35%) | catalogued as rs767993138, COSV71384006; called by muse, mutect2, varscan2
- NQO1 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 122/334 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.052); catalogued as COSV57731653; called by muse, mutect2, varscan2
- NRXN2 | c.1922T>C p.L641P | Missense Mutation (SNP) | VAF 297/912 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1482567921; called by muse, mutect2, varscan2
- NXPE2 | c.815G>A p.R272K | Missense Mutation (SNP) | VAF 109/404 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64940291; called by muse, mutect2, varscan2
- NYAP1 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 367/1120 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs1383033722; called by muse, mutect2, varscan2
- OR10AG1 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 121/394 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs867351355, COSV100400066, COSV56635322; called by muse, mutect2, varscan2
- OR10J3 | c.844C>T p.H282Y | Missense Mutation (SNP) | VAF 130/464 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs761528731, COSV59953616; called by muse, mutect2, varscan2
- OR13C2 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV73377724; called by muse, mutect2, varscan2
- OR2A7 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 71/568 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV71827973; called by muse, mutect2, varscan2
- OR2J2 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 188/741 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs191240319, COSV65848126, COSV65848370; called by muse, mutect2
- OR4K17 | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 82/318 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV59649129; called by muse, mutect2, varscan2
- OR4L1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 134/450 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV59850776; called by muse, mutect2, varscan2
- OR51I1 | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 160/446 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0.011); catalogued as rs750457267; called by muse, varscan2
- OR52E6 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 126/414 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1428334209, COSV61431747, COSV61432662; called by muse, mutect2, varscan2
- OR52N4 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 115/436 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs765711389, COSV57893602; called by muse, mutect2, varscan2
- OR8D4 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 145/490 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV100361964; called by muse, mutect2, varscan2
- OTOA | c.1883C>T p.S628F (on ENST00000286149; = p.S614F on NM_144672.4) | Missense Mutation (SNP) | VAF 100/369 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs868666952, COSV53753266; called by muse, mutect2, varscan2
- PASD1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV64855120; called by muse, mutect2, varscan2
- PCDHGA9 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 123/243 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1312851147; called by muse, mutect2, varscan2
- PCK2 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 132/455 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs911134655; called by muse, mutect2, varscan2
- PCLO | c.11956C>T p.L3986F | Missense Mutation (SNP) | VAF 128/391 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1376068163; called by muse, mutect2, varscan2
- PDE2A | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 319/930 reads (34%) | catalogued as rs1215167552; called by muse, mutect2, varscan2
- PDE3A | c.3274G>A p.E1092K | Missense Mutation (SNP) | VAF 120/443 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as rs909760212; called by muse, mutect2, varscan2
- PDE4A | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 223/660 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs773511169; called by muse, mutect2, varscan2
- PES1 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 237/734 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1172610740; called by muse, mutect2, varscan2
- PLA2G2C | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 156/455 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.011); catalogued as rs770249103; called by muse, mutect2, varscan2
- PLCB2 | c.2156G>A p.R719Q | Missense Mutation (SNP) | VAF 185/607 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as rs768839429, COSV53031582; called by muse, mutect2, varscan2
- PLCXD3 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 129/463 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV60606249; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1536dup p.K513Qfs*114 | Frame Shift Ins (INS) | VAF 270/921 reads (29%) | catalogued as rs1393457707; called by mutect2, pindel, varscan2
- PPP4R3C | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 125/254 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV69080886; called by muse, mutect2, varscan2
- PRAMEF20 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 76/231 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs202075096; called by muse, mutect2, varscan2
- PRDM9 | c.1309C>T p.Q437* | Nonsense Mutation (SNP) | VAF 132/446 reads (30%) | catalogued as COSV57006493; called by muse, mutect2, varscan2
- PRRC2B | c.6265C>T p.P2089S | Missense Mutation (SNP) | VAF 239/460 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.319); catalogued as COSV57644709; called by muse, mutect2, varscan2
- PTBP2 | c.354G>A p.M118I (on ENST00000426398 / NM_001300986.2; = p.M110I on NM_021190.4) | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as rs899775990, COSV64625938; called by muse, mutect2, varscan2
- PTEN | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 104/275 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs746152219, CM1513163, COSV64296809, COSV64296832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTGFR | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 140/301 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557660883, COSV66114307; called by muse, mutect2, varscan2
- PTPRQ | c.1568C>T p.S523L (on ENST00000616559; = p.S481L on NM_001145026.2) | Missense Mutation (SNP) | VAF 140/465 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.355); catalogued as rs575857456, COSV99030994; called by muse, mutect2, varscan2
- RFPL4A | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 80/607 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.191); catalogued as rs753429804; called by muse, mutect2, varscan2
- RFPL4AL1 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 97/820 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs1448733777; called by muse, mutect2, varscan2
- RXFP2 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 122/395 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752942567, COSV53633745, COSV53641972; called by muse, mutect2, varscan2
- RYR1 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 104/388 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.853); catalogued as COSV62113607; called by muse, mutect2, varscan2
- SAMD9 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 116/433 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV66074557, COSV66076449; called by muse, mutect2, varscan2
- SCNN1G | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 60/252 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs773317054, COSV55599443; called by muse, mutect2, varscan2
- SERPINA9 | c.1028G>A p.R343K | Missense Mutation (SNP) | VAF 151/566 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs770704186, COSV100098486; called by muse, mutect2, varscan2
- SERPINA9 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 88/262 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as rs775122463, COSV54079282; called by muse, mutect2, varscan2
- SETD7 | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 172/512 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV56801549, COSV56801723; called by mutect2, varscan2
- SH3RF1 | c.1925C>G p.T642R | Missense Mutation (SNP) | VAF 264/836 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV52925376; called by muse, mutect2
- SHROOM3 | c.5698C>T p.R1900C | Missense Mutation (SNP) | VAF 148/434 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770837589, COSV56032949; called by muse, mutect2, varscan2
- SLC12A5 | c.2995G>A p.D999N (on ENST00000454036 / NM_001134771.2; = p.D976N on NM_020708.5) | Missense Mutation (SNP) | VAF 134/453 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs765995687, COSV51646365; called by muse, mutect2, varscan2
- SLC1A7 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 149/447 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV57016171; called by muse, mutect2, varscan2
- SLC2A14 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 112/367 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746537796; called by muse, mutect2, varscan2
- SLC6A12 | c.1423G>A p.V475M | Missense Mutation (SNP) | VAF 112/423 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs1354817882; called by muse, mutect2, varscan2
- SLITRK5 | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 146/471 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs772894574, COSV61522158; called by muse, mutect2, varscan2
- SMARCA4 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 272/807 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); catalogued as rs1568417458, COSV60791099; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCA5 | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 98/324 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51648325; called by muse, mutect2, varscan2
- SNX31 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 175/479 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1313705428; called by muse, mutect2, varscan2
- SP3 | c.1870C>T p.H624Y | Missense Mutation (SNP) | VAF 107/293 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs1257600145; called by muse, mutect2, varscan2
- SPEM2 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 276/860 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs181105702; called by muse, mutect2, varscan2
- SPINK5 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs751741124; called by muse, mutect2, varscan2
- ST8SIA2 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 199/621 reads (32%) | catalogued as COSV51572667; called by muse, mutect2, varscan2
- STRA6 | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 126/405 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV51433323; called by muse, mutect2, varscan2
- STS | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 79/164 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV54271934; called by muse, mutect2, varscan2
- STXBP5L | c.2426G>A p.R809Q | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.171); catalogued as rs1268529223, COSV99070967; called by muse, mutect2, varscan2
- SYNE1 | c.8222G>A p.R2741K (on ENST00000367255 / NM_182961.4; = p.R2748K on NM_033071.3) | Missense Mutation (SNP) | VAF 111/377 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs181218387; called by muse, mutect2, varscan2
- SYNPO2L | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 135/290 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867702811; called by muse, mutect2, varscan2
- SYT17 | c.1245G>A p.M415I | Missense Mutation (SNP) | VAF 93/299 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV62548194; called by muse, mutect2, varscan2
- SYTL3 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 275/830 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs760246645; called by muse, mutect2, varscan2
- TCEAL9 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 73/290 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as rs903298456; called by muse, mutect2, varscan2
- TCHHL1 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 160/533 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs376159135; called by muse, mutect2, varscan2
- TF | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 98/260 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.031); catalogued as COSV53924691; called by muse, mutect2
- TGM4 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 156/498 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV99942155; called by muse, mutect2
- THEM5 | c.245G>A p.W82* | Nonsense Mutation (SNP) | VAF 156/522 reads (30%) | catalogued as rs778682602; called by muse, mutect2, varscan2
- TRIM49C | c.1229G>A p.G410E | Missense Mutation (SNP) | VAF 113/382 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV71510258; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 134/398 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100709204; called by muse, mutect2, varscan2
- TRIML2 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 159/542 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58715295; called by muse, mutect2, varscan2
- TTC21B | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 137/436 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); catalogued as COSV54627555; called by muse, mutect2, varscan2
- TTC29 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 92/294 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs1169819657; called by muse, mutect2, varscan2
- TTN | c.74995G>A p.E24999K (on ENST00000591111; = p.E17575K on NM_003319.4) | Missense Mutation (SNP) | VAF 125/253 reads (49%) | PolyPhen benign (0.298); catalogued as COSV60062786; called by muse, mutect2, varscan2
- UBALD2 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 274/800 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53154430; called by muse, mutect2, varscan2
- UBE4B | c.1682C>T p.P561L (on ENST00000343090 / NM_001105562.3; = p.P432L on NM_006048.5) | Missense Mutation (SNP) | VAF 123/419 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1482482521; called by muse, mutect2, varscan2
- UBQLN3 | c.1673G>A p.G558D | Missense Mutation (SNP) | VAF 108/424 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs760176228; called by muse, mutect2, varscan2
- UGT2B15 | c.1571G>A p.G524E | Missense Mutation (SNP) | VAF 76/234 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV57733488; called by muse, mutect2, varscan2
- UNKL | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 286/773 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs754823063; called by muse, mutect2, varscan2
- USP33 | c.1836G>T p.L612F | Missense Mutation (SNP) | VAF 69/130 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62470867; called by muse, mutect2, varscan2
- WEE2 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 145/663 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs267601320, COSV66879894; called by muse, mutect2, varscan2
- WLS | c.753G>A p.W251* | Nonsense Mutation (SNP) | VAF 167/521 reads (32%) | catalogued as rs753958149; called by muse, mutect2, varscan2
- XIRP2 | c.394G>A p.E132K (on ENST00000628543; = p.E307K on NM_152381.6) | Missense Mutation (SNP) | VAF 121/369 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV54691504; called by muse, mutect2, varscan2
- ZEB1 | c.2594G>A p.G865E | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58042383; called by muse, mutect2, varscan2
- ZFHX3 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 188/561 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.328); catalogued as COSV51711567; called by muse, mutect2, varscan2
- ZFHX4 | c.8150C>T p.T2717I | Missense Mutation (SNP) | VAF 131/522 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs752747502, COSV50831743; called by muse, mutect2, varscan2
- ZFHX4 | c.8797C>T p.R2933* | Nonsense Mutation (SNP) | VAF 144/435 reads (33%) | catalogued as COSV50549536; called by muse, mutect2, varscan2
- ZMYM1 | c.2702C>A p.S901* | Nonsense Mutation (SNP) | VAF 85/215 reads (40%) | catalogued as COSV100721071; called by muse, mutect2, varscan2
- ZMYM2 | c.3758C>T p.T1253M | Missense Mutation (SNP) | VAF 137/480 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs984014970, COSV67037176; called by muse, varscan2
- ZMYND10 | c.1193G>C p.S398T | Missense Mutation (SNP) | VAF 176/534 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV51601655; called by muse, mutect2, varscan2
- ZNF775 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 407/1150 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1040642592; called by muse, mutect2, varscan2
- ZNF804A | c.3622C>T p.L1208F | Missense Mutation (SNP) | VAF 110/210 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV56469060; called by muse, mutect2, varscan2
- AC021072.1 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 137/493 reads (28%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACKR3 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 200/404 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM7 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS18 | c.3629G>A p.G1210E | Missense Mutation (SNP) | VAF 105/353 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADCY4 | c.162G>A p.E54= | Splice Region (SNP) | VAF 196/586 reads (33%) | called by muse, varscan2
- AFF4 | c.3145A>T p.K1049* | Nonsense Mutation (SNP) | VAF 60/125 reads (48%) | called by muse, mutect2, varscan2
- ALPK2 | c.2068T>A p.S690T | Missense Mutation (SNP) | VAF 154/479 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- ANAPC7 | c.29A>T p.E10V | Missense Mutation (SNP) | VAF 134/445 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANK1 | c.223A>G p.T75A | Missense Mutation (SNP) | VAF 93/308 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- ANKFN1 | c.741G>T p.Q247H | Missense Mutation (SNP) | VAF 122/484 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ANKRD13A | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 134/430 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APC | c.8433C>G p.N2811K | Missense Mutation (SNP) | VAF 220/454 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- APOB | c.3133A>T p.T1045S | Missense Mutation (SNP) | VAF 86/306 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- AQP8 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 161/475 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- AQR | c.1589A>C p.N530T | Missense Mutation (SNP) | VAF 147/511 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ARHGEF15 | c.1181C>T p.T394I | Missense Mutation (SNP) | VAF 250/836 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ARHGEF5 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 183/979 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARID2 | c.973_979del p.I325* | Frame Shift Del (DEL) | VAF 56/278 reads (20%) | called by pindel, varscan2
- ASPM | c.3970A>C p.K1324Q | Missense Mutation (SNP) | VAF 121/413 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ASPSCR1 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 162/495 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ATN1 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 206/760 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, varscan2
- ATP10D | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 127/434 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- ATP11C | c.1720C>T p.P574S | Missense Mutation (SNP) | VAF 90/403 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ATP2B4 | c.3279G>A p.W1093* | Nonsense Mutation (SNP) | VAF 127/426 reads (30%) | called by muse, mutect2, varscan2
- ATP4A | c.3040G>A p.D1014N | Missense Mutation (SNP) | VAF 158/526 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCL11B | c.1892G>A p.G631E (on ENST00000357195 / NM_001282237.2; = p.G560E on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 170/458 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- BICD1 | c.2693C>T p.P898L | Missense Mutation (SNP) | VAF 184/580 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BMP2 | c.502C>T p.H168Y | Missense Mutation (SNP) | VAF 124/340 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- BMP8A | c.1136A>G p.Y379C | Missense Mutation (SNP) | VAF 269/830 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BPI | c.101C>T p.P34L (on ENST00000262865; = p.P30L on NM_001725.3) | Missense Mutation (SNP) | VAF 223/724 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRWD3 | c.3301G>A p.D1101N | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BSCL2 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 130/430 reads (30%) | called by muse, varscan2
- BTNL3 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 113/231 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- C16orf91 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 340/913 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- C19orf47 | c.78G>A p.A26= | Splice Region (SNP) | VAF 204/630 reads (32%) | called by muse, mutect2, varscan2
- CACNG7 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 380/1054 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CAMTA1 | c.797G>A p.G266D | Missense Mutation (SNP) | VAF 197/586 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CCDC42 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 117/300 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CCHCR1 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 359/1082 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- CDH12 | c.1219A>G p.T407A | Missense Mutation (SNP) | VAF 123/382 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- CELSR1 | c.5725G>A p.D1909N | Missense Mutation (SNP) | VAF 210/654 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- CFAP69 | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- COL4A1 | c.4995T>A p.C1665* | Nonsense Mutation (SNP) | VAF 180/476 reads (38%) | called by muse, mutect2, varscan2
- COL8A1 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 203/672 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- COPG2 | c.2303A>G p.N768S | Missense Mutation (SNP) | VAF 130/437 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- CRB1 | c.3589G>A p.A1197T | Missense Mutation (SNP) | VAF 134/436 reads (31%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- CSMD2 | c.970A>G p.N324D | Missense Mutation (SNP) | VAF 171/537 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CSNK1G2 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 231/663 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- CWH43 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 104/321 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- CYP2J2 | c.1468T>A p.S490T | Missense Mutation (SNP) | VAF 144/471 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- DACH2 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 83/278 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- DHX29 | c.3872C>T p.T1291I | Missense Mutation (SNP) | VAF 96/198 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- DHX58 | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 267/824 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DKK3 | c.561C>G p.D187E | Missense Mutation (SNP) | VAF 135/460 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- DLC1 | c.2428C>T p.P810S (on ENST00000276297 / NM_001348081.2; = p.P373S on NM_006094.5) | Missense Mutation (SNP) | VAF 189/574 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH11 | c.1472A>G p.E491G | Missense Mutation (SNP) | VAF 147/444 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH11 | c.5068C>T p.Q1690* | Nonsense Mutation (SNP) | VAF 93/340 reads (27%) | called by muse, mutect2, varscan2
- DNAH11 | c.12934G>A p.G4312R | Missense Mutation (SNP) | VAF 92/276 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH2 | c.6550G>A p.D2184N | Missense Mutation (SNP) | VAF 201/678 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK4 | c.1842G>A p.K614= | Splice Region (SNP) | VAF 70/202 reads (35%) | called by muse, mutect2, varscan2
- DRAM2 | c.424C>T p.L142F | Missense Mutation (SNP) | VAF 136/296 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DYNC2H1 | c.4940C>T p.S1647F | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- ENPP4 | c.1205T>A p.I402N | Missense Mutation (SNP) | VAF 147/467 reads (31%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- EPB41L2 | c.1072C>T p.L358F | Missense Mutation (SNP) | VAF 140/449 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- EPX | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 248/843 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERICH6B | c.1285C>T p.H429Y | Missense Mutation (SNP) | VAF 119/351 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- FERMT1 | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 43/231 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FES | c.2386T>G p.C796G | Missense Mutation (SNP) | VAF 299/814 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FILIP1L | c.558G>A p.M186I | Missense Mutation (SNP) | VAF 43/310 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- FLNA | c.5419G>A p.E1807K (on ENST00000369850 / NM_001110556.2; = p.E1799K on NM_001456.3) | Missense Mutation (SNP) | VAF 232/703 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- FLT1 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 105/350 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLT3 | c.2192C>T p.S731L | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FLVCR2 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 156/467 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- FSIP2 | c.15699T>G p.Y5233* | Nonsense Mutation (SNP) | VAF 70/164 reads (43%) | called by muse, mutect2, varscan2
- FYTTD1 | c.946A>T p.T316S | Missense Mutation (SNP) | VAF 127/374 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GALNT15 | c.1534A>T p.T512S | Missense Mutation (SNP) | VAF 155/410 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GCNA | c.1956G>A p.R652= | Splice Region (SNP) | VAF 117/363 reads (32%) | called by muse, mutect2, varscan2
- GDPD4 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 105/369 reads (28%) | called by muse, mutect2, varscan2
- GFM1 | c.884T>A p.V295E | Missense Mutation (SNP) | VAF 123/413 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- GLIPR1L1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 90/269 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- GLP2R | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 125/433 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GNL1 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 104/319 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GPR108 | c.957C>G p.S319R (on ENST00000264080 / NM_001080452.1; = p.S77R on NM_020171.2) | Missense Mutation (SNP) | VAF 179/582 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- HAND2 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 330/945 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.017); called by mutect2, varscan2
- HAPLN2 | c.12G>A p.W4* | Nonsense Mutation (SNP) | VAF 250/643 reads (39%) | called by muse, mutect2, varscan2
- HDAC4 | c.3169A>G p.T1057A | Missense Mutation (SNP) | VAF 221/428 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HDAC4 | c.2773del p.D925Mfs*32 | Frame Shift Del (DEL) | VAF 207/474 reads (44%) | called by mutect2, pindel, varscan2
- HECTD2 | c.2135G>A p.G712E | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- HS1BP3 | c.783C>T p.D261= | Splice Region (SNP) | VAF 167/422 reads (40%) | called by muse, mutect2, varscan2
- HSPG2 | c.10475A>G p.N3492S | Missense Mutation (SNP) | VAF 166/470 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- HYDIN | c.9737C>T p.S3246F | Missense Mutation (SNP) | VAF 40/278 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2
- HYDIN | c.626C>A p.S209Y | Missense Mutation (SNP) | VAF 63/328 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- IBA57 | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 399/1150 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- IFT27 | c.451G>A p.E151K (on ENST00000433985 / NM_001363003.2; = p.E150K on NM_006860.5) | Missense Mutation (SNP) | VAF 148/473 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGFN1 | c.2116G>A p.D706N (on ENST00000295591 / NM_001367841.1; = p.D3163N on NM_001164586.2) | Missense Mutation (SNP) | VAF 262/833 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- IGSF1 | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 169/562 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IL10 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 175/538 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- ILF2 | c.631T>C p.F211L | Missense Mutation (SNP) | VAF 114/421 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- IQCA1L | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 103/330 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ITIH3 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 128/471 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITM2B | c.688A>T p.K230* | Nonsense Mutation (SNP) | VAF 97/272 reads (36%) | called by muse, mutect2, varscan2
- ITPR1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 107/368 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCND2 | c.673T>C p.Y225H | Missense Mutation (SNP) | VAF 172/534 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- KCNT2 | c.3260C>T p.P1087L | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1217 | c.5114A>G p.H1705R | Missense Mutation (SNP) | VAF 157/293 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF3B | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 144/514 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.08); called by muse, varscan2
- KIRREL2 | c.73C>T p.H25Y | Missense Mutation (SNP) | VAF 237/676 reads (35%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLC3 | c.968A>T p.K323M | Missense Mutation (SNP) | VAF 195/578 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KMT2C | c.6605C>T p.P2202L | Missense Mutation (SNP) | VAF 184/560 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- KMT2D | c.15389C>T p.T5130I | Missense Mutation (SNP) | VAF 235/753 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- KRT13 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 337/1047 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- KRTAP13-1 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 90/348 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- KSR2 | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 235/750 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- LAS1L | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 134/445 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LHX9 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 125/405 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- LILRB3 | c.1712C>A p.P571H (on ENST00000346401; = p.P559H on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 162/628 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- LILRB3 | c.1711C>T p.P571S (on ENST00000346401; = p.P559S on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 165/632 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- LIPN | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 123/317 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- LMF1 | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 259/773 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LMOD3 | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 214/569 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRC14B | c.834G>A p.M278I | Missense Mutation (SNP) | VAF 338/958 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- LRRC7 | c.1396C>T p.P466S (on ENST00000651989 / NM_001370785.2; = p.P433S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/280 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LUZP4 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 210/588 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- MACROD2 | c.877G>A p.E293K (on ENST00000642719; = p.E265K on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/247 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- MAML1 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 229/424 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAMLD1 | c.1703C>T p.S568F | Missense Mutation (SNP) | VAF 301/908 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- MAP3K15 | c.2896A>T p.T966S | Missense Mutation (SNP) | VAF 303/588 reads (52%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MBD3 | c.413del p.F138Sfs*6 | Frame Shift Del (DEL) | VAF 120/462 reads (26%) | called by mutect2, pindel, varscan2
- MGAM2 | c.5693C>T p.P1898L | Missense Mutation (SNP) | VAF 257/560 reads (46%) | SIFT tolerated, low confidence (0.08); called by muse, mutect2, varscan2
- MIA3 | c.900A>T p.E300D | Missense Mutation (SNP) | VAF 128/396 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MROH5 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 165/507 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- MYH7 | c.2243C>T p.S748F | Missense Mutation (SNP) | VAF 118/406 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYLK2 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 261/742 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- MYO18B | c.2678A>T p.D893V | Missense Mutation (SNP) | VAF 71/255 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- MYO18B | c.6580C>T p.P2194S | Missense Mutation (SNP) | VAF 209/575 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MYO1F | c.1573T>C p.F525L | Missense Mutation (SNP) | VAF 197/586 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- MYO1G | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 160/492 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYOZ3 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 172/336 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- NAALADL2 | c.1383A>C p.Q461H | Missense Mutation (SNP) | VAF 110/412 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NBPF4 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- NEB | c.13745C>T p.P4582L | Missense Mutation (SNP) | VAF 94/280 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEXMIF | c.3625G>A p.E1209K | Missense Mutation (SNP) | VAF 192/637 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- NFIC | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 151/539 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NID2 | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 93/336 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NOTCH4 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 353/1096 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- NPHP4 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 109/407 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- NPHP4 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 110/412 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- NUTM1 | c.224A>T p.D75V | Missense Mutation (SNP) | VAF 124/392 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- OR10G8 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 112/314 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR10J4 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 139/415 reads (33%) | called by muse, mutect2, varscan2
- OR11L1 | c.730C>G p.H244D | Missense Mutation (SNP) | VAF 139/392 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2L8 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 93/265 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- OR2T34 | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 177/635 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.329); called by muse, mutect2
- OR4A47 | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 143/466 reads (31%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4A8 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 92/286 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OR52E8 | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 164/496 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- OR56A4 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 118/418 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6K6 | c.761G>A p.G254E (on ENST00000368144; = p.G230E on NM_001005184.1) | Missense Mutation (SNP) | VAF 166/492 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- OR6V1 | c.476del p.L159Pfs*41 | Frame Shift Del (DEL) | VAF 235/822 reads (29%) | called by mutect2, pindel, varscan2
- OR8J2 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OR8J2 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR8K1 | c.845T>A p.V282E | Missense Mutation (SNP) | VAF 140/449 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PCDHA10 | c.69G>A p.W23* | Nonsense Mutation (SNP) | VAF 188/334 reads (56%) | called by muse, mutect2, varscan2
- PCDHGC4 | c.212A>C p.N71T | Missense Mutation (SNP) | VAF 186/412 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.137); called by muse, mutect2
- PHKA1 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 102/330 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- PI4KA | c.4177C>T p.P1393S | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PILRB | c.473C>T p.T158I | Missense Mutation (SNP) | VAF 152/471 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PLAAT5 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 77/334 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PLXNA4 | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 182/578 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLXNC1 | c.2444G>T p.S815I | Missense Mutation (SNP) | VAF 120/388 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PODNL1 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 119/489 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- POGLUT2 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 127/436 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POLR3B | c.2153C>T p.P718L | Missense Mutation (SNP) | VAF 89/371 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPFIA1 | c.3078G>T p.R1026S | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- PRAMEF18 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 110/872 reads (13%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.464); called by muse, mutect2
- PRAMEF19 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 48/918 reads (5%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.453); called by muse, mutect2
- PRDX6 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 95/327 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- PTPRK | c.2679C>T p.S893= (on ENST00000368215 / NM_001291984.2; = p.S894= on NM_002844.4) | Splice Region (SNP) | VAF 80/267 reads (30%) | called by muse, mutect2, varscan2
- PUS7L | c.35G>T p.S12I | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- RASGRF2 | c.2147G>A p.G716D | Missense Mutation (SNP) | VAF 163/326 reads (50%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RBM20 | c.2090G>A p.G697E | Missense Mutation (SNP) | VAF 189/393 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF175 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 93/320 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- RP1 | c.3823A>G p.N1275D | Missense Mutation (SNP) | VAF 125/415 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPTN | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 112/350 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- RUNX1T1 | c.1610C>T p.S537L (on ENST00000265814 / NM_001198628.1; = p.S510L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 254/739 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RWDD1 | c.439A>G p.T147A | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- RXYLT1 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RYR1 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 146/532 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCAPER | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 91/287 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCEL | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SCP2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SERPINB12 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 150/492 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SETD1A | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 188/517 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SH3RF1 | c.1927C>A p.H643N | Missense Mutation (SNP) | VAF 255/822 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.067); called by muse, mutect2
- SIAH1 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 185/563 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SLAMF6 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 137/438 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SLC13A1 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 104/303 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SLC16A14 | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 173/313 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- SLC22A3 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 101/258 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- SLC22A7 | c.557G>A p.G186D (on ENST00000372585 / NM_153320.2; = p.G184D on NM_006672.3) | Missense Mutation (SNP) | VAF 221/683 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- SLC26A9 | c.1411C>T p.L471F | Missense Mutation (SNP) | VAF 148/518 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC43A1 | c.86T>A p.V29E | Missense Mutation (SNP) | VAF 167/545 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC6A4 | c.817G>A p.G273S | Missense Mutation (SNP) | VAF 148/433 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC7A13 | c.262T>A p.F88I | Missense Mutation (SNP) | VAF 192/545 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- SLC9A2 | c.1433C>A p.T478N | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- SLCO3A1 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 218/668 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLFN14 | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 141/424 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPEM3 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 198/628 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SRCIN1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 398/1155 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- SREBF2 | c.1993G>A p.D665N | Missense Mutation (SNP) | VAF 215/651 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- STK31 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 75/286 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- STYX | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 251/783 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TAF6L | c.277_278delinsT p.P93Sfs*15 | Frame Shift Del (DEL) | VAF 158/707 reads (22%) | called by pindel, varscan2*
- TECRL | c.227T>A p.L76Q | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- TLR7 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 122/254 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- TM7SF3 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- TMC8 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 232/776 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM72 | c.475A>C p.T159P | Missense Mutation (SNP) | VAF 175/328 reads (53%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- TMPRSS11A | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 97/362 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- TNR | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 120/410 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, varscan2
- TRAV12-3 | c.171G>T p.W57C | Missense Mutation (SNP) | VAF 130/401 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRDN | c.2102G>A p.G701E | Missense Mutation (SNP) | VAF 99/391 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPM2 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 164/495 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TTN | c.86797G>A p.E28933K (on ENST00000591111; = p.E21509K on NM_003319.4) | Missense Mutation (SNP) | VAF 181/362 reads (50%) | PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- TTN | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 163/332 reads (49%) | PolyPhen benign (0.116); called by muse, mutect2, varscan2
- UNC80 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 147/294 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- USO1 | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 92/271 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- USP17L2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 94/215 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- USPL1 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 104/407 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- VAT1L | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 97/419 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- VIRMA | c.4612G>T p.A1538S | Missense Mutation (SNP) | VAF 92/288 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWF | c.5485G>A p.D1829N | Missense Mutation (SNP) | VAF 113/404 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- WDR82 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 124/335 reads (37%) | called by muse, mutect2, varscan2
- XIRP2 | c.3514G>A p.V1172M (on ENST00000628543; = p.V1347M on NM_152381.6) | Missense Mutation (SNP) | VAF 90/330 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- YIPF7 | c.717T>G p.I239M | Missense Mutation (SNP) | VAF 128/386 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ZDHHC17 | c.1505del p.S502Ffs*35 | Frame Shift Del (DEL) | VAF 81/314 reads (26%) | called by mutect2, pindel, varscan2
- ZMYM6 | c.3052G>A p.V1018M | Missense Mutation (SNP) | VAF 136/385 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ZNF276 | c.1838C>T p.P613L (on ENST00000443381 / NM_001113525.2; = p.P538L on NM_152287.4) | Missense Mutation (SNP) | VAF 298/874 reads (34%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF343 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 182/527 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF518B | c.3095C>T p.S1032L | Missense Mutation (SNP) | VAF 133/397 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF541 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 267/677 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- ZNF735 | c.547A>C p.K183Q | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ABCA13 | c.13981C>T p.L4661= | Silent (SNP) | VAF 167/537 reads (31%) | catalogued as rs1247935886, COSV68950896; called by muse, mutect2, varscan2
- ABCC3 | c.447C>T p.I149= | Silent (SNP) | VAF 145/514 reads (28%) | catalogued as rs1037736149, COSV53319978; called by muse, mutect2, varscan2
- ABCC8 | c.2109C>T p.I703= | Silent (SNP) | VAF 156/457 reads (34%) | catalogued as COSV56856370; called by muse, mutect2, varscan2
- ACD | c.150C>T p.L50= | Silent (SNP) | VAF 271/873 reads (31%) | catalogued as COSV54667962; called by muse, mutect2, varscan2
- ADAMDEC1 | c.336G>A p.E112= | Silent (SNP) | VAF 93/328 reads (28%) | catalogued as rs767695894, COSV99836221; called by muse, mutect2, varscan2
- ADGRF4 | c.1014G>A p.K338= | Silent (SNP) | VAF 90/296 reads (30%) | called by muse, mutect2, varscan2
- AFF3 | c.3483C>T p.H1161= | Silent (SNP) | VAF 205/679 reads (30%) | catalogued as rs371178462; called by muse, mutect2, varscan2
- ALPK3 | c.3423G>A p.E1141= | Silent (SNP) | VAF 219/702 reads (31%) | called by muse, mutect2, varscan2
- AMZ1 | c.894C>T p.I298= | Silent (SNP) | VAF 234/751 reads (31%) | catalogued as rs773132642; called by muse, mutect2, varscan2
- ANO2 | c.2478C>T p.P826= (on ENST00000356134 / NM_001278597.3; = p.P830= on NM_001278596.3) | Silent (SNP) | VAF 146/429 reads (34%) | called by muse, mutect2, varscan2
- APBB1 | c.394C>T p.L132= | Silent (SNP) | VAF 196/584 reads (34%) | called by muse, varscan2
- APOL2 | c.981C>T p.I327= | Silent (SNP) | VAF 97/341 reads (28%) | called by muse, mutect2, varscan2
- ARIH2 | c.765C>T p.V255= | Silent (SNP) | VAF 75/265 reads (28%) | catalogued as rs753216184; called by muse, mutect2, varscan2
- ASAP3 | c.1287C>T p.I429= | Silent (SNP) | VAF 344/1036 reads (33%) | catalogued as rs1161920287; called by muse, mutect2, varscan2
- ASB15 | c.876G>A p.L292= | Silent (SNP) | VAF 50/184 reads (27%) | called by muse, mutect2, varscan2
- ASIC4 | c.306C>T p.D102= | Silent (SNP) | VAF 226/453 reads (50%) | called by muse, mutect2, varscan2
- ASTN1 | c.1398G>A p.R466= | Silent (SNP) | VAF 152/408 reads (37%) | called by muse, mutect2, varscan2
- ATG2A | c.3174G>A p.K1058= | Silent (SNP) | VAF 188/609 reads (31%) | called by muse, mutect2, varscan2
- ATN1 | c.1416C>T p.A472= | Silent (SNP) | VAF 208/767 reads (27%) | catalogued as rs781808775; called by muse, varscan2
- ATXN7L2 | c.1128G>A p.R376= | Silent (SNP) | VAF 285/570 reads (50%) | called by muse, mutect2, varscan2
- BCL6 | c.882C>T p.F294= | Silent (SNP) | VAF 236/756 reads (31%) | catalogued as COSV51651724, COSV51651738; called by muse, mutect2, varscan2
- BCL9L | c.1135C>T p.L379= | Silent (SNP) | VAF 237/766 reads (31%) | catalogued as rs1186595579; called by muse, mutect2, varscan2
- BCL9L | c.1134C>T p.A378= | Silent (SNP) | VAF 237/770 reads (31%) | catalogued as rs753393624, COSV99419518; called by muse, mutect2, varscan2
- BMPER | c.987G>A p.T329= | Silent (SNP) | VAF 83/313 reads (27%) | catalogued as rs1424454427, COSV51826024, COSV99779711; called by muse, mutect2, varscan2
- BTG4 | c.231G>A p.V77= | Silent (SNP) | VAF 83/421 reads (20%) | called by muse, mutect2, varscan2
- C11orf16 | c.159C>T p.P53= | Silent (SNP) | VAF 139/449 reads (31%) | catalogued as rs1336486684; called by muse, mutect2, varscan2
- C16orf96 | c.1986C>T p.A662= | Silent (SNP) | VAF 135/488 reads (28%) | called by muse, mutect2, varscan2
- C1QTNF1 | c.609C>T p.N203= | Silent (SNP) | VAF 239/717 reads (33%) | called by muse, mutect2, varscan2
- C4orf17 | c.276C>T p.S92= | Silent (SNP) | VAF 172/583 reads (30%) | called by muse, mutect2
- CATSPERB | c.2319G>A p.L773= | Silent (SNP) | VAF 40/228 reads (18%) | called by muse, mutect2, varscan2
- CCDC88B | c.459G>A p.R153= | Silent (SNP) | VAF 190/609 reads (31%) | called by muse, mutect2, varscan2
- CDH13 | c.2049G>A p.R683= | Silent (SNP) | VAF 189/544 reads (35%) | called by muse, mutect2, varscan2
- CDH6 | c.804C>T p.F268= | Silent (SNP) | VAF 124/404 reads (31%) | called by muse, mutect2, varscan2
- CEACAM4 | c.660C>T p.P220= | Silent (SNP) | VAF 204/694 reads (29%) | catalogued as rs1555800317; called by muse, mutect2, varscan2
- CELA2A | c.669G>A p.Q223= | Silent (SNP) | VAF 182/609 reads (30%) | called by muse, mutect2, varscan2
- CFAP54 | c.1185G>A p.E395= | Silent (SNP) | VAF 143/415 reads (34%) | catalogued as rs1200331214; called by muse, mutect2, varscan2
- CHAC1 | c.141C>T p.F47= | Silent (SNP) | VAF 260/911 reads (29%) | catalogued as rs922731000; called by muse, mutect2, varscan2
- CIRBP | c.171T>A p.I57= | Silent (SNP) | VAF 124/435 reads (29%) | catalogued as rs1472790683; called by muse, mutect2, varscan2
- CMYA5 | c.4506C>T p.V1502= | Silent (SNP) | VAF 144/269 reads (54%) | called by muse, mutect2, varscan2
- COL5A3 | c.2592C>T p.I864= | Silent (SNP) | VAF 202/738 reads (27%) | called by muse, mutect2, varscan2
- CPA6 | c.1227C>A p.L409= | Silent (SNP) | VAF 128/439 reads (29%) | called by muse, mutect2, varscan2
- CPLANE1 | c.9099C>T p.I3033= | Silent (SNP) | VAF 75/262 reads (29%) | called by muse, mutect2, varscan2
- CPT1C | c.1074G>A p.L358= | Silent (SNP) | VAF 252/721 reads (35%) | catalogued as rs1174977117; called by muse, mutect2, varscan2
- CSK | c.1143C>T p.S381= | Silent (SNP) | VAF 89/357 reads (25%) | catalogued as COSV54975225; called by muse, mutect2, varscan2
- CSMD1 | c.10101G>A p.G3367= (on ENST00000520002; = p.G3366= on NM_033225.6) | Silent (SNP) | VAF 118/407 reads (29%) | catalogued as rs760727138, COSV59277440; called by muse, mutect2, varscan2
- CTNND2 | c.372G>A p.V124= | Silent (SNP) | VAF 68/285 reads (24%) | called by muse, mutect2, varscan2
- CXCR4 | c.315G>A p.G105= | Silent (SNP) | VAF 206/646 reads (32%) | catalogued as rs761898625, COSV99602999; called by muse, varscan2
- CYP2C18 | c.657C>T p.F219= | Silent (SNP) | VAF 44/88 reads (50%) | catalogued as COSV53669799; called by muse, mutect2, varscan2
- CYP7B1 | c.1296G>A p.G432= | Silent (SNP) | VAF 123/391 reads (31%) | catalogued as rs1342380224, COSV59592573; called by muse, mutect2, varscan2
- DAAM1 | c.714G>A p.K238= | Silent (SNP) | VAF 172/512 reads (34%) | called by muse, mutect2, varscan2
- DAB1 | c.1197C>T p.F399= (on ENST00000371231; = p.F366= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 226/675 reads (33%) | catalogued as COSV100976317; called by muse, mutect2, varscan2
- DBF4B | c.1488C>T p.F496= | Silent (SNP) | VAF 230/736 reads (31%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.594C>T p.F198= | Silent (SNP) | VAF 328/1009 reads (33%) | catalogued as COSV64421793; called by muse, mutect2, varscan2
- DDR1 | c.18G>A p.L6= | Silent (SNP) | VAF 215/762 reads (28%) | called by muse, mutect2, varscan2
- DENND11 | c.240G>A p.V80= | Silent (SNP) | VAF 251/1023 reads (25%) | called by muse, mutect2, varscan2
- DENND2B | c.297C>T p.F99= | Silent (SNP) | VAF 240/717 reads (33%) | catalogued as rs200752970; called by muse, mutect2, varscan2
- DGAT1 | c.264C>T p.I88= | Silent (SNP) | VAF 144/472 reads (31%) | called by muse, mutect2, varscan2
- DGKA | c.159C>T p.F53= | Silent (SNP) | VAF 136/406 reads (33%) | called by muse, mutect2, varscan2
- DLGAP3 | c.1839C>T p.I613= | Silent (SNP) | VAF 329/970 reads (34%) | catalogued as rs758905561, COSV52393197; called by muse, mutect2, varscan2
- DNAH10 | c.5910C>T p.I1970= (on ENST00000409039; = p.I1909= on NM_207437.3) | Silent (SNP) | VAF 136/437 reads (31%) | called by muse, mutect2, varscan2
- DNAH10 | c.6129G>A p.A2043= (on ENST00000409039; = p.A1982= on NM_207437.3) | Silent (SNP) | VAF 124/366 reads (34%) | catalogued as rs767940904, COSV68997499; called by muse, mutect2, varscan2
- DNAH12 | c.7197G>A p.R2399= (on ENST00000351747; = p.R3267= on NM_001366028.2) | Silent (SNP) | VAF 111/417 reads (27%) | called by muse, mutect2, varscan2
- DNASE1L1 | c.99G>A p.K33= | Silent (SNP) | VAF 222/648 reads (34%) | catalogued as rs1557188209; called by muse, mutect2, varscan2
- DND1 | c.948G>A p.G316= | Silent (SNP) | VAF 101/1024 reads (10%) | called by muse, mutect2
- DPEP2 | c.1416C>T p.V472= | Silent (SNP) | VAF 114/438 reads (26%) | called by muse, mutect2, varscan2
- DRD1 | c.39G>A p.G13= | Silent (SNP) | VAF 143/284 reads (50%) | catalogued as rs369853177; called by muse, mutect2, varscan2
- EDDM3B | c.267C>T p.F89= | Silent (SNP) | VAF 125/437 reads (29%) | catalogued as COSV58747142; called by muse, mutect2, varscan2
- EFHC1 | c.1290C>T p.I430= | Silent (SNP) | VAF 101/295 reads (34%) | called by muse, mutect2, varscan2
- ENPP6 | c.501C>T p.A167= | Silent (SNP) | VAF 86/254 reads (34%) | called by muse, mutect2, varscan2
- ERVV-2 | c.1464G>A p.R488= | Silent (SNP) | VAF 84/239 reads (35%) | catalogued as rs867175435, COSV74153437; called by muse, mutect2, varscan2
- ETS2 | c.1326C>T p.F442= | Silent (SNP) | VAF 172/567 reads (30%) | catalogued as COSV62872282; called by muse, mutect2, varscan2
- F8A1 | c.1038A>C p.P346= | Silent (SNP) | VAF 105/744 reads (14%) | called by muse, mutect2, varscan2
- FAM155B | c.759G>A p.L253= | Silent (SNP) | VAF 57/1106 reads (5%) | called by muse, mutect2
- FAM222B | c.1155C>T p.A385= | Silent (SNP) | VAF 269/824 reads (33%) | called by muse, mutect2, varscan2
- FAM83D | c.963C>T p.S321= | Silent (SNP) | VAF 230/667 reads (34%) | called by muse, mutect2, varscan2
- FAT3 | c.4899G>A p.T1633= | Silent (SNP) | VAF 145/510 reads (28%) | catalogued as rs772117922; called by muse, mutect2, varscan2
- FAT4 | c.13146G>A p.G4382= | Silent (SNP) | VAF 109/363 reads (30%) | catalogued as rs925363038, COSV100630546; called by muse, mutect2, varscan2
- FBN3 | c.990C>T p.V330= | Silent (SNP) | VAF 252/692 reads (36%) | called by muse, mutect2, varscan2
- FCN1 | c.828A>T p.G276= | Silent (SNP) | VAF 189/371 reads (51%) | catalogued as COSV65662702; called by muse, mutect2, varscan2
- FER1L5 | c.3621G>A p.R1207= (on ENST00000623019; = p.R1180= on NM_001293083.2) | Silent (SNP) | VAF 198/629 reads (31%) | called by muse, mutect2, varscan2
- FGD5 | c.204C>T p.V68= | Silent (SNP) | VAF 184/508 reads (36%) | called by muse, mutect2, varscan2
- FMO1 | c.837G>A p.L279= | Silent (SNP) | VAF 69/292 reads (24%) | catalogued as COSV61444872; called by muse, mutect2, varscan2
- FRY | c.5973C>T p.I1991= | Silent (SNP) | VAF 165/527 reads (31%) | catalogued as rs1163664497, COSV66575782; called by muse, mutect2, varscan2
- GABRB2 | c.129C>T p.L43= | Silent (SNP) | VAF 76/189 reads (40%) | called by muse, mutect2, varscan2
- GAS2L2 | c.2490G>A p.V830= | Silent (SNP) | VAF 182/726 reads (25%) | called by muse, mutect2
- GATA4 | c.960G>A p.R320= | Silent (SNP) | VAF 98/350 reads (28%) | catalogued as COSV58736190; called by muse, mutect2, varscan2
- GJA8 | c.498C>T p.I166= | Silent (SNP) | VAF 182/516 reads (35%) | catalogued as rs1435123500, COSV53788642, COSV53788663; called by muse, mutect2, varscan2
- GRAMD1B | c.1362G>A p.A454= | Silent (SNP) | VAF 126/393 reads (32%) | catalogued as rs759704937; called by muse, mutect2, varscan2
- GRM8 | c.216G>A p.G72= | Silent (SNP) | VAF 147/506 reads (29%) | called by muse, mutect2, varscan2
- HCAR2 | c.1086T>A p.S362= | Silent (SNP) | VAF 121/334 reads (36%) | called by muse, mutect2, varscan2
- HS3ST2 | c.963C>T p.L321= | Silent (SNP) | VAF 171/596 reads (29%) | catalogued as rs539271647, COSV54467207; called by muse, mutect2, varscan2
- HTR1D | c.933C>T p.I311= | Silent (SNP) | VAF 248/679 reads (37%) | catalogued as COSV58448976; called by muse, mutect2, varscan2
- HTR3B | c.501G>A p.Q167= | Silent (SNP) | VAF 145/430 reads (34%) | called by muse, mutect2, varscan2
- HTR3B | c.852C>T p.F284= | Silent (SNP) | VAF 170/524 reads (32%) | catalogued as COSV99492294; called by muse, mutect2, varscan2
- ICAM1 | c.471G>A p.L157= | Silent (SNP) | VAF 324/948 reads (34%) | catalogued as COSV99321233; called by muse, mutect2, varscan2
- IFT122 | c.642C>T p.I214= (on ENST00000348417 / NM_052989.3; = p.I265= on NM_052985.4) | Silent (SNP) | VAF 120/436 reads (28%) | catalogued as COSV56203297; called by muse, mutect2, varscan2
- IGHV3-73 | c.13C>T p.L5= | Silent (SNP) | VAF 36/141 reads (26%) | called by muse, mutect2, varscan2
- IGKV1D-12 | c.180G>A p.Q60= | Silent (SNP) | VAF 64/316 reads (20%) | catalogued as rs747710090; called by muse, varscan2
- IL27 | c.531G>A p.R177= | Silent (SNP) | VAF 145/743 reads (20%) | called by mutect2, varscan2
- IPO9 | c.2547G>T p.L849= | Silent (SNP) | VAF 97/258 reads (38%) | called by muse, mutect2, varscan2
- IRF6 | c.1161G>A p.R387= | Silent (SNP) | VAF 84/314 reads (27%) | catalogued as COSV65420471; called by muse, mutect2, varscan2
- ITGA8 | c.1926A>G p.G642= | Silent (SNP) | VAF 106/204 reads (52%) | called by muse, mutect2, varscan2
- ITGAM | c.2283C>T p.F761= (on ENST00000648685 / NM_001145808.2; = p.F760= on NM_000632.4) | Silent (SNP) | VAF 106/297 reads (36%) | called by muse, mutect2, varscan2
- IVD | c.459C>T p.L153= (on ENST00000651168; = p.L150= on NM_002225.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 89/342 reads (26%) | called by muse, mutect2, varscan2
- IZUMO1 | c.1041G>A p.S347= | Silent (SNP) | VAF 76/382 reads (20%) | called by muse, mutect2
- JCAD | c.579G>A p.R193= | Silent (SNP) | VAF 170/331 reads (51%) | catalogued as COSV64759627; called by muse, mutect2, varscan2
- JPH1 | c.1614C>T p.I538= | Silent (SNP) | VAF 222/650 reads (34%) | called by muse, mutect2, varscan2
- KCND2 | c.897G>A p.R299= | Silent (SNP) | VAF 123/432 reads (28%) | catalogued as COSV58584707; called by muse, mutect2, varscan2
- KCNJ10 | c.483C>T p.I161= | Silent (SNP) | VAF 235/617 reads (38%) | catalogued as rs1269942126; called by muse, mutect2, varscan2
- KCNQ3 | c.762C>T p.I254= | Silent (SNP) | VAF 153/451 reads (34%) | catalogued as COSV66478161, COSV66478593; called by muse, mutect2, varscan2
- KMT2D | c.3888C>T p.A1296= | Silent (SNP) | VAF 170/578 reads (29%) | catalogued as rs988352935; called by muse, mutect2, varscan2
- KSR2 | c.1125C>T p.F375= | Silent (SNP) | VAF 166/511 reads (32%) | catalogued as rs767407680, COSV56669188; called by muse, mutect2, varscan2
- LGR6 | c.1470G>A p.K490= (on ENST00000367278 / NM_001017403.1; = p.K438= on NM_021636.3) | Silent (SNP) | VAF 156/546 reads (29%) | catalogued as COSV55157497; called by muse, mutect2, varscan2
- LRP11 | c.1086C>T p.A362= | Silent (SNP) | VAF 148/432 reads (34%) | called by muse, mutect2, varscan2
- LRRC3B | c.741G>A p.K247= | Silent (SNP) | VAF 89/352 reads (25%) | called by muse, mutect2, varscan2
- LRRK1 | c.474C>T p.A158= | Silent (SNP) | VAF 270/804 reads (34%) | called by muse, mutect2, varscan2
- LRRN3 | c.2124C>T p.S708= | Silent (SNP) | VAF 68/191 reads (36%) | catalogued as COSV57823823; called by muse, mutect2, varscan2
- M1AP | c.1344G>A p.L448= | Silent (SNP) | VAF 173/658 reads (26%) | called by muse, mutect2, varscan2
- MAGEB10 | c.819C>T p.F273= | Silent (SNP) | VAF 171/382 reads (45%) | called by muse, mutect2, varscan2
- MAGEB18 | c.372G>A p.T124= | Silent (SNP) | VAF 134/480 reads (28%) | catalogued as rs773395698, COSV57463775; called by muse, mutect2, varscan2
- MAOB | c.1545G>A p.G515= | Silent (SNP) | VAF 171/342 reads (50%) | called by muse, mutect2, varscan2
- MEX3D | c.1839C>T p.V613= | Silent (SNP) | VAF 469/1332 reads (35%) | catalogued as rs1277958296; called by muse, mutect2, varscan2
- MGAM2 | c.2352G>A p.R784= | Silent (SNP) | VAF 144/312 reads (46%) | called by muse, mutect2, varscan2
- MICU3 | c.126C>G p.P42= | Silent (SNP) | VAF 415/1210 reads (34%) | called by muse, mutect2, varscan2
- MMP26 | c.63C>T p.P21= | Silent (SNP) | VAF 106/390 reads (27%) | called by muse, mutect2, varscan2
- MUC12 | c.6492C>T p.F2164= (on ENST00000379442; = p.F2021= on NM_001164462.1) | Silent (SNP) | VAF 27/418 reads (6%) | called by muse, mutect2
- MUC12 | c.7914C>T p.F2638= (on ENST00000379442; = p.F2495= on NM_001164462.1) | Silent (SNP) | VAF 209/3354 reads (6%) | called by muse, mutect2
- MX2 | c.1264C>T p.L422= | Silent (SNP) | VAF 98/333 reads (29%) | called by muse, mutect2, varscan2
- MYH1 | c.3363G>A p.E1121= | Silent (SNP) | VAF 138/443 reads (31%) | called by muse, mutect2, varscan2
- MYH2 | c.5688C>T p.N1896= | Silent (SNP) | VAF 62/199 reads (31%) | catalogued as rs146066739; called by muse, mutect2, varscan2
- MYLK2 | c.558G>A p.T186= | Silent (SNP) | VAF 261/744 reads (35%) | catalogued as rs140695242; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- MYO6 | c.1737C>T p.I579= | Silent (SNP) | VAF 80/211 reads (38%) | called by muse, mutect2, varscan2
- MYRIP | c.1059G>A p.G353= | Silent (SNP) | VAF 152/534 reads (28%) | catalogued as rs769665003, COSV100219728; called by muse, mutect2, varscan2
- NBEA | c.2475C>T p.V825= | Silent (SNP) | VAF 76/272 reads (28%) | called by muse, mutect2, varscan2
- NBPF4 | c.153C>T p.S51= | Silent (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
- NDST1 | c.915C>T p.R305= | Silent (SNP) | VAF 187/369 reads (51%) | called by muse, mutect2, varscan2
- NFASC | c.2187C>T p.S729= (on ENST00000339876 / NM_001378329.1; = p.S725= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 115/401 reads (29%) | catalogued as rs1033101322; called by muse, mutect2, varscan2
- NKTR | c.4273C>A p.R1425= | Silent (SNP) | VAF 115/395 reads (29%) | called by muse, mutect2, varscan2
- NRXN1 | c.1179G>A p.G393= | Silent (SNP) | VAF 109/356 reads (31%) | catalogued as rs200528030, COSV58436267; called by muse, mutect2, varscan2
- NXPE2 | c.1299G>A p.R433= | Silent (SNP) | VAF 146/456 reads (32%) | called by muse, mutect2, varscan2
- OBSCN | c.18469C>T p.L6157= | Silent (SNP) | VAF 273/762 reads (36%) | called by muse, mutect2, varscan2
- OR10J5 | c.375C>T p.A125= | Silent (SNP) | VAF 152/500 reads (30%) | called by muse, mutect2, varscan2
- OR1R1P | c.312C>T p.F104= | Silent (SNP) | VAF 226/723 reads (31%) | called by muse, mutect2, varscan2
- OR2A12 | c.90C>T p.F30= | Silent (SNP) | VAF 156/442 reads (35%) | catalogued as COSV68821675; called by muse, mutect2, varscan2
- OR2T10 | c.21C>T p.T7= | Silent (SNP) | VAF 109/163 reads (67%) | called by muse, mutect2, varscan2
- OR4M1 | c.135C>T p.I45= | Silent (SNP) | VAF 86/266 reads (32%) | catalogued as rs776142493, COSV60059590; called by muse, varscan2
- OR4M1 | c.201C>T p.A67= | Silent (SNP) | VAF 76/225 reads (34%) | catalogued as rs1471484777; called by muse, varscan2
- OR5L1 | c.753C>T p.F251= | Silent (SNP) | VAF 142/442 reads (32%) | catalogued as rs1381189325, COSV61734552, COSV61735291, COSV61735761; called by muse, mutect2, varscan2
- OR8D1 | c.858C>T p.N286= | Silent (SNP) | VAF 65/265 reads (25%) | catalogued as COSV63441867; called by muse, mutect2, varscan2
- OR8D1 | c.255C>T p.F85= | Silent (SNP) | VAF 165/481 reads (34%) | catalogued as COSV63441709; called by muse, mutect2, varscan2
- OR8K3 | c.366C>T p.L122= | Silent (SNP) | VAF 185/549 reads (34%) | called by muse, mutect2, varscan2
- PABPC4 | c.690C>T p.S230= | Silent (SNP) | VAF 91/333 reads (27%) | catalogued as COSV63293255; called by muse, mutect2, varscan2
- PADI1 | c.867C>T p.F289= | Silent (SNP) | VAF 152/592 reads (26%) | called by muse, mutect2
- PARP4 | c.4068C>A p.P1356= | Silent (SNP) | VAF 173/523 reads (33%) | called by muse, mutect2, varscan2
- PCDH10 | c.648G>A p.G216= | Silent (SNP) | VAF 222/528 reads (42%) | catalogued as rs754308045; called by mutect2, varscan2
- PCDHA2 | c.168G>A p.L56= | Silent (SNP) | VAF 271/532 reads (51%) | called by muse, mutect2, varscan2
- PCDHGC4 | c.210G>A p.V70= | Silent (SNP) | VAF 184/412 reads (45%) | called by muse, mutect2
- PDGFRA | c.1633C>T p.L545= | Silent (SNP) | VAF 139/495 reads (28%) | called by muse, mutect2, varscan2
- PDP1 | c.1368A>C p.G456= | Silent (SNP) | VAF 115/364 reads (32%) | called by muse, mutect2, varscan2
- PDZRN4 | c.1152T>C p.Y384= (on ENST00000402685 / NM_001164595.2; = p.Y126= on NM_013377.4) | Silent (SNP) | VAF 51/197 reads (26%) | called by muse, mutect2, varscan2
- PDZRN4 | c.2949G>A p.K983= (on ENST00000402685 / NM_001164595.2; = p.K725= on NM_013377.4) | Silent (SNP) | VAF 121/415 reads (29%) | called by muse, mutect2, varscan2
- PIGN | c.57C>T p.I19= | Silent (SNP) | VAF 91/357 reads (25%) | called by muse, mutect2, varscan2
- PIP5K1B | c.1389C>T p.V463= | Silent (SNP) | VAF 123/265 reads (46%) | called by muse, mutect2, varscan2
- PLAT | c.1263G>A p.Q421= | Silent (SNP) | VAF 241/746 reads (32%) | catalogued as rs963660927, COSV54276178; called by muse, mutect2, varscan2
- PLCB4 | c.1149C>T p.I383= | Silent (SNP) | VAF 95/318 reads (30%) | catalogued as COSV99594501; called by muse, mutect2, varscan2
- PODNL1 | c.294C>T p.L98= | Silent (SNP) | VAF 120/493 reads (24%) | called by muse, mutect2, varscan2
- POLI | c.1158G>A p.Q386= | Silent (SNP) | VAF 69/225 reads (31%) | called by muse, mutect2, varscan2
- POLR1B | c.1668C>T p.V556= | Silent (SNP) | VAF 312/470 reads (66%) | called by muse, mutect2, varscan2
- POM121L2 | c.1335G>A p.G445= | Silent (SNP) | VAF 185/584 reads (32%) | called by muse, mutect2, varscan2
- PPDPFL | c.180C>T p.F60= | Silent (SNP) | VAF 108/386 reads (28%) | catalogued as COSV57462131; called by muse, mutect2, varscan2
- PPP1R12A | c.2658C>T p.S886= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- PRDM9 | c.678G>A p.K226= | Silent (SNP) | VAF 204/655 reads (31%) | called by muse, mutect2, varscan2
- PROKR1 | c.978C>T p.I326= | Silent (SNP) | VAF 165/510 reads (32%) | catalogued as rs1231056509, COSV58139244; called by muse, mutect2, varscan2
- PRRC2B | c.3615C>T p.L1205= | Silent (SNP) | VAF 232/419 reads (55%) | catalogued as rs1410846905; called by muse, mutect2, varscan2
- PRSS58 | c.192G>A p.V64= | Silent (SNP) | VAF 170/432 reads (39%) | catalogued as COSV73488882; called by muse, mutect2, varscan2
- PTPRQ | c.1128G>A p.G376= (on ENST00000616559; = p.G334= on NM_001145026.2) | Silent (SNP) | VAF 75/273 reads (27%) | called by muse, mutect2, varscan2
- PYHIN1 | c.831T>A p.R277= | Silent (SNP) | VAF 122/332 reads (37%) | called by muse, mutect2, varscan2
- RAG1 | c.1293G>A p.K431= | Silent (SNP) | VAF 185/603 reads (31%) | called by muse, mutect2, varscan2
- RAI1 | c.3156C>T p.L1052= | Silent (SNP) | VAF 313/900 reads (35%) | called by muse, mutect2, varscan2
- RELN | c.7707C>T p.L2569= | Silent (SNP) | VAF 132/398 reads (33%) | called by muse, mutect2, varscan2
- RFPL4A | c.348G>A p.R116= | Silent (SNP) | VAF 88/446 reads (20%) | catalogued as COSV70455334; called by muse, mutect2, varscan2
- RGL3 | c.858C>T p.G286= | Silent (SNP) | VAF 269/915 reads (29%) | called by muse, mutect2, varscan2
- RGSL1 | c.1980G>A p.R660= | Silent (SNP) | VAF 112/328 reads (34%) | called by muse, mutect2, varscan2
- RP1L1 | c.5889C>T p.S1963= | Silent (SNP) | VAF 195/582 reads (34%) | catalogued as rs1183761722; called by muse, mutect2, varscan2
- RP1L1 | c.18G>A p.R6= | Silent (SNP) | VAF 158/443 reads (36%) | catalogued as rs1195162355, COSV100262185; called by muse, mutect2, varscan2
- RPS6KA1 | c.2184G>A p.R728= | Silent (SNP) | VAF 164/536 reads (31%) | called by muse, mutect2, varscan2
- RRM2 | c.9C>T p.S3= | Silent (SNP) | VAF 275/869 reads (32%) | catalogued as rs752116944; called by muse, mutect2, varscan2
- RYR1 | c.8850C>T p.S2950= | Silent (SNP) | VAF 103/361 reads (29%) | catalogued as rs765217271; called by muse, mutect2, varscan2
- SCN10A | c.132G>A p.Q44= | Silent (SNP) | VAF 165/545 reads (30%) | catalogued as rs138739418, COSV71860793; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN5A | c.1290G>A p.K430= | Silent (SNP) | VAF 131/428 reads (31%) | called by muse, mutect2, varscan2
- SCNN1A | c.1974G>A p.G658= | Silent (SNP) | VAF 196/739 reads (27%) | called by muse, mutect2
- SEC14L4 | c.348C>T p.S116= | Silent (SNP) | VAF 155/471 reads (33%) | called by muse, mutect2, varscan2
- SELE | c.999C>T p.F333= | Silent (SNP) | VAF 192/635 reads (30%) | catalogued as rs267598160, COSV60978345; called by muse, mutect2, varscan2
- SERINC2 | c.270C>T p.S90= (on ENST00000373709 / NM_178865.5; = p.S94= on NM_018565.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 316/941 reads (34%) | called by muse, mutect2, varscan2
- SERPINA7 | c.1140C>T p.F380= | Silent (SNP) | VAF 176/596 reads (30%) | catalogued as COSV100568491; called by muse, mutect2, varscan2
- SERPINC1 | c.801G>A p.R267= | Silent (SNP) | VAF 131/449 reads (29%) | called by muse, mutect2, varscan2
- SETBP1 | c.2424C>T p.L808= | Silent (SNP) | VAF 142/461 reads (31%) | catalogued as COSV56318145, COSV99953978; called by muse, mutect2, varscan2
- SEZ6 | c.621G>A p.G207= | Silent (SNP) | VAF 206/610 reads (34%) | catalogued as COSV100252662; called by muse, mutect2, varscan2
- SEZ6L | c.2526G>A p.G842= | Silent (SNP) | VAF 175/618 reads (28%) | catalogued as rs1432743398; called by muse, mutect2, varscan2
- SLC15A1 | c.2028G>A p.A676= | Silent (SNP) | VAF 164/494 reads (33%) | catalogued as rs754073444; called by muse, mutect2, varscan2
- SLC28A1 | c.861G>A p.Q287= | Silent (SNP) | VAF 128/385 reads (33%) | catalogued as COSV54476778; called by muse, mutect2, varscan2
- SLC38A3 | c.1158C>T p.F386= | Silent (SNP) | VAF 167/541 reads (31%) | called by muse, mutect2, varscan2
- SLC4A5 | c.669C>T p.P223= | Silent (SNP) | VAF 130/559 reads (23%) | called by muse, mutect2, varscan2
- SLC9A5 | c.1776C>T p.G592= | Silent (SNP) | VAF 145/417 reads (35%) | called by muse, mutect2, varscan2
- SLC9A9 | c.1155C>T p.F385= | Silent (SNP) | VAF 111/356 reads (31%) | called by muse, mutect2, varscan2
- SLCO6A1 | c.1479G>A p.G493= | Silent (SNP) | VAF 60/127 reads (47%) | catalogued as COSV65810481; called by muse, mutect2, varscan2
- SMG1 | c.5376G>A p.L1792= | Silent (SNP) | VAF 134/472 reads (28%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.801C>T p.I267= | Silent (SNP) | VAF 93/354 reads (26%) | called by muse, mutect2, varscan2
- SPTB | c.5905C>T p.L1969= | Silent (SNP) | VAF 160/513 reads (31%) | called by muse, mutect2, varscan2
- SREBF2 | c.2565C>T p.S855= | Silent (SNP) | VAF 88/316 reads (28%) | catalogued as rs772439466; called by muse, mutect2, varscan2
- SRPX2 | c.1032C>T p.L344= | Silent (SNP) | VAF 116/435 reads (27%) | called by muse, mutect2, varscan2
- SSU72P5 | c.465C>T p.I155= | Silent (SNP) | VAF 59/411 reads (14%) | called by muse, mutect2, varscan2
- STIM2 | c.1641G>A p.P547= | Silent (SNP) | VAF 301/848 reads (35%) | catalogued as rs758088279; called by muse, varscan2
- STON1 | c.1350G>A p.G450= | Silent (SNP) | VAF 143/414 reads (35%) | called by muse, mutect2, varscan2
- TCF19 | c.615C>T p.P205= | Silent (SNP) | VAF 283/830 reads (34%) | catalogued as rs766932507; called by muse, mutect2, varscan2
- TESPA1 | c.1326C>T p.L442= (on ENST00000316577 / NM_001098815.3; = p.L304= on NM_014796.2 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 129/410 reads (31%) | catalogued as COSV57257134; called by muse, mutect2, varscan2
- THAP4 | c.1575C>T p.I525= | Silent (SNP) | VAF 241/731 reads (33%) | catalogued as rs780293026, COSV58710433; called by muse, mutect2, varscan2
- TIMP4 | c.663C>T p.I221= | Silent (SNP) | VAF 114/363 reads (31%) | catalogued as rs1340979729, COSV55138724; called by muse, mutect2, varscan2
- TMEM176B | c.354G>A p.K118= | Silent (SNP) | VAF 160/532 reads (30%) | called by muse, mutect2, varscan2
- TMPRSS7 | c.1626G>A p.R542= (on ENST00000452346; = p.R416= on NM_001042575.2) | Silent (SNP) | VAF 123/397 reads (31%) | called by muse, mutect2, varscan2
- TMX3 | c.1023T>C p.D341= | Silent (SNP) | VAF 54/159 reads (34%) | called by muse, varscan2
- TOX3 | c.510T>A p.P170= | Silent (SNP) | VAF 254/776 reads (33%) | called by muse, mutect2, varscan2
- TPO | c.2253G>A p.G751= | Silent (SNP) | VAF 408/620 reads (66%) | catalogued as rs1169165027; called by muse, mutect2, varscan2
- TPPP2 | c.438G>A p.R146= | Silent (SNP) | VAF 166/547 reads (30%) | catalogued as rs201065546; called by muse, mutect2, varscan2
- TPTE | c.469T>C p.L157= (on ENST00000618007 / NM_199261.4; = p.L139= on NM_199259.4) | Silent (SNP) | VAF 13/222 reads (6%) | called by muse, mutect2
- TREML1 | c.237C>T p.L79= | Silent (SNP) | VAF 237/706 reads (34%) | catalogued as rs773100755; called by muse, mutect2, varscan2
- TRIM29 | c.888G>A p.K296= | Silent (SNP) | VAF 79/268 reads (29%) | called by muse, mutect2, varscan2
- TRIM29 | c.69G>A p.S23= | Silent (SNP) | VAF 359/985 reads (36%) | catalogued as rs770071793; called by muse, mutect2, varscan2
- TRIP12 | c.1191C>T p.S397= | Silent (SNP) | VAF 140/247 reads (57%) | catalogued as rs753869840, COSV52267994; called by muse, mutect2, varscan2
- TRPM5 | c.2241C>T p.F747= | Silent (SNP) | VAF 257/714 reads (36%) | called by muse, mutect2, varscan2
- TTC7B | c.2451T>C p.A817= | Silent (SNP) | VAF 255/806 reads (32%) | called by muse, mutect2, varscan2
- TUBA8 | c.406C>T p.L136= | Silent (SNP) | VAF 134/402 reads (33%) | called by muse, mutect2, varscan2
- TULP1 | c.651G>A p.R217= | Silent (SNP) | VAF 183/578 reads (32%) | called by muse, mutect2, varscan2
- UGT3A1 | c.1386C>T p.I462= | Silent (SNP) | VAF 187/669 reads (28%) | catalogued as COSV57100765; called by muse, mutect2, varscan2
- ULK4 | c.24G>A p.E8= | Silent (SNP) | VAF 105/337 reads (31%) | called by muse, mutect2, varscan2
- UTP25 | c.1218C>T p.N406= | Silent (SNP) | VAF 143/474 reads (30%) | catalogued as rs764697718; called by muse, mutect2, varscan2
- VAV1 | c.270G>A p.R90= | Silent (SNP) | VAF 144/411 reads (35%) | catalogued as COSV58380044; called by muse, mutect2, varscan2
- WDR27 | c.2292G>A p.G764= | Silent (SNP) | VAF 74/281 reads (26%) | catalogued as rs1375702580; called by muse, mutect2, varscan2
- WDR87 | c.376C>T p.L126= | Silent (SNP) | VAF 194/571 reads (34%) | catalogued as COSV58208802; called by muse, mutect2, varscan2
- WDTC1 | c.336C>T p.A112= | Silent (SNP) | VAF 165/556 reads (30%) | catalogued as rs377585210; called by muse, mutect2, varscan2
- WHAMM | c.567C>T p.A189= | Silent (SNP) | VAF 262/805 reads (33%) | catalogued as rs1334519498; called by muse, varscan2
- XKR5 | c.1590G>A p.Q530= | Silent (SNP) | VAF 180/579 reads (31%) | catalogued as rs1236749622, COSV68398430; called by muse, mutect2, varscan2
- ZFPM2 | c.2814C>T p.T938= | Silent (SNP) | VAF 162/470 reads (34%) | called by muse, varscan2
- ZNF230 | c.1155C>T p.V385= | Silent (SNP) | VAF 133/428 reads (31%) | catalogued as COSV101431964; called by muse, mutect2, varscan2
- ZNF285 | c.1725G>A p.K575= | Silent (SNP) | VAF 74/211 reads (35%) | catalogued as rs1175367767; called by muse, mutect2, varscan2
- ZNF488 | c.441C>T p.V147= | Silent (SNP) | VAF 274/508 reads (54%) | catalogued as rs1174323059; called by muse, mutect2, varscan2
- ZNF536 | c.3135C>T p.A1045= | Silent (SNP) | VAF 217/648 reads (33%) | catalogued as COSV62821189, COSV62829667; called by muse, mutect2, varscan2
- ZNF594 | c.837T>C p.S279= | Silent (SNP) | VAF 175/545 reads (32%) | catalogued as rs1344495842, COSV101280497, COSV101280507; called by muse, mutect2, varscan2
- ZNF607 | c.360G>A p.Q120= | Silent (SNP) | VAF 82/262 reads (31%) | called by muse, mutect2, varscan2
- ZNF726 | c.930G>A p.E310= | Silent (SNP) | VAF 167/553 reads (30%) | catalogued as rs1448642922; called by muse, mutect2, varscan2
- ZNF835 | c.24C>T p.A8= | Silent (SNP) | VAF 150/407 reads (37%) | called by muse, mutect2, varscan2
- ZNF99 | c.2196C>T p.P732= | Silent (SNP) | VAF 78/326 reads (24%) | catalogued as COSV101233814; called by muse, mutect2, varscan2
- ADRA1A | chr8:26766133 C>T | 3'Flank (SNP) | VAF 73/288 reads (25%) | catalogued as COSV52375268; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823874 G>A | 5'Flank (SNP) | VAF 68/251 reads (27%) | called by muse, mutect2, varscan2
- AMDHD2 | c.*684A>T | 3'UTR (SNP) | VAF 222/641 reads (35%) | called by muse, mutect2, varscan2
- ANKRD33 | c.664+43G>A | Intron (SNP) | VAF 160/632 reads (25%) | catalogued as rs906737970, COSV56606197; called by muse, mutect2, varscan2
- ANXA8 | c.-166G>A | 5'UTR (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- ASIC2 | c.556-179572G>C | Intron (SNP) | VAF 382/1096 reads (35%) | called by muse, mutect2, varscan2
- C2orf16 | chr2:27571650 C>T | 5'Flank (SNP) | VAF 153/438 reads (35%) | called by muse, mutect2, varscan2
- CEACAM19 | c.-210C>T | 5'UTR (SNP) | VAF 153/487 reads (31%) | called by muse, mutect2, varscan2
- DMRTC2 | c.816+70C>T | Intron (SNP) | VAF 264/818 reads (32%) | called by muse, mutect2, varscan2
- DNAH14 | c.3052-21541C>T | Intron (SNP) | VAF 71/224 reads (32%) | catalogued as rs749639957, COSV60736918; called by muse, mutect2, varscan2
- GCSH | chr16:81101146 C>T | 5'Flank (SNP) | VAF 111/380 reads (29%) | called by muse, mutect2, varscan2
- GNAS | chr20:58850764 C>T | 5'Flank (SNP) | VAF 254/741 reads (34%) | catalogued as rs1182143365; called by muse, mutect2, varscan2
- IGFN1 | c.1241+3169G>A | Intron (SNP) | VAF 243/661 reads (37%) | catalogued as rs1262065305; called by muse, mutect2, varscan2
- ISCA2 | c.-1G>A | 5'UTR (SNP) | VAF 172/578 reads (30%) | catalogued as rs1482088986; called by muse, mutect2, varscan2
- JUP | c.*14+64C>T | Intron (SNP) | VAF 230/725 reads (32%) | called by muse, mutect2, varscan2
- JUP | c.*14+63C>T | Intron (SNP) | VAF 230/723 reads (32%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-19148C>T | Intron (SNP) | VAF 55/269 reads (20%) | called by muse, mutect2, varscan2
- MSANTD1 | chr4:3261387 G>A | 3'Flank (SNP) | VAF 181/555 reads (33%) | called by muse, mutect2, varscan2
- MUCL3 | c.947-1130C>T | Intron (SNP) | VAF 252/729 reads (35%) | called by muse, mutect2, varscan2
- MYL3 | chr3:46833761 G>A | 3'Flank (SNP) | VAF 217/649 reads (33%) | called by muse, mutect2, varscan2
- NHSL2 | c.-286C>T | 5'UTR (SNP) | VAF 214/636 reads (34%) | called by muse, mutect2, varscan2
- NPLOC4 | c.1669+23C>T | Intron (SNP) | VAF 329/911 reads (36%) | called by muse, mutect2, varscan2
- PIEZO2 | c.2492+4437C>T | Intron (SNP) | VAF 96/226 reads (42%) | catalogued as rs907548476; called by muse, mutect2, varscan2
- SLC22A17 | n.940C>T | RNA (SNP) | VAF 277/823 reads (34%) | catalogued as COSV52835169; called by muse, mutect2, varscan2
6 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 6 other) are not listed here.
